Surgical pathology report (de-identified scan), TCGA case TCGA-IZ-8195, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-IZ-8195-01A (Primary Tumor).

[page 1 of 3]
MRN

Name

Encounter
Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
StatusTime Received
Order Number

Results

Final

Source of Specimen
LEFT KIDNEY AND ADRENAL GLAND-FINAL DIAGNOSIS:
LEFT KIDNEY AND ADRENAL GLAND-
RENAL CELL CARCINOMA WITH EXTENSIVE NECROSIS AND HEMORRHAGE (see
synoptic report below).
MINUTE (LESS THAN 0.1 CM) CORTICAL FOCUS OF PAPILLARY CHANGE
(SLIDE A12), NOT DEFINITE FOR TUMOR.

SYNOPTIC REPORT:

RENAL CELL CARCINOMA, LIMITED TO KIDNEY/RENAL TISSUE EXAMINED

PROPORTION OF SARCOMATOID COMPONENT: 0 %

SPECIMEN LATERALITY: LEFT

TUMOR FOCALITY: FOCAL

TUMOR SIZE: 9 X 9 X 6 CM

HISTOLOGIC TYPE: PAPILLARY GRANULAR CELL TYPE

HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): 2/4

TNM STAGE: pT2a, pNX, pMX

Prepared

[page 2 of 3]
LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 0

LYMPHATIC (SMALL VESSEL) INVASION: NOT FOUND

SPECIMEN TYPE: RADICAL NEPHRECTOMY

SPECIMEN SIZE: 22 X 15 X 11 CM

ADRENAL GLAND, NEGATIVE FOR TUMOR

NO TUMOR SEEN AT SPECIMEN MARGINS

Case Clinical Information
LEFT RENAL MASS

Gross Description

Received in formalin labeled with the patient's name and "left kidney and adrenal gland" consists of a 1060 gram total nephrectomy specimen with attached perinephric fat and attached adrenal gland. Overall the dimensions of the specimen measure 22 x 15 x 11 cm. The kidney proper measures 15 x 10.5 x 6.5 cm. The ureter is identified at the hilum measuring 1.0 cm. The remainder of the vessels at the hilum are identified with clamps. The attached adrenal gland has a somewhat disrupted appearance measuring 5 x 1.5 x 1.0 cm. The cut surface of the adrenal gland has a gold-yellow appearance. The kidney is bivalved and in the upper pole the cut surface reveals a capsulated necrotic mass measuring 9 x 9 x 6 cm and grossly appears to push the capsule in the area of the mass. The cortex in the lower pole has a tan smooth appearance measuring 1.1 cm. The mass measures to the UP junction 2.9 cm. Further serially sectioning the mass has a very friable necrotic hemorrhagic appearance. Representative sections are submitted as follows: A1 = left ureter resection margin; A2 = remainder of vessels at hilum; A3-A4 = full thickness cross sections of attached adrenal gland; A5-A6 = full thickness cross sections of UP junction; A7-A9 = full thickness cross sections demonstrating mass, capsule and fatty tissue; A10-A12 = full thickness cross sections of parenchyma lower pole that is not involved. Also tissue was taken for research. Additional section code: A13-A16= full thickness cross sections of tumor to kidney and

Pre

[page 3 of 3]
cortex.

Procedure

A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
A. AA ROUTINE H&E X1 BLOCK.4
H&E X1
A. AA ROUTINE H&E X1 BLOCK.5
H&E X1
A. AA ROUTINE H&E X1 BLOCK.6
H&E X1
A. AA ROUTINE H&E X1 BLOCK.7
H&E X1
A. AA ROUTINE H&E X1 BLOCK.8
H&E X1
A. AA ROUTINE H&E X1 BLOCK.9
H&E X1
A. AA ROUTINE H&E X1 BLOCK.10
H&E X1
A. AA ROUTINE H&E X1 BLOCK.11
H&E X1
A. AA ROUTINE H&E X1 BLOCK.12
H&E X1
A. AA ROUTINE H&E X1 BLOCK.13
H&E X1
A. AA ROUTINE H&E X1 BLOCK.14
H&E X1
A. AA ROUTINE H&E X1 BLOCK.15
H&E X1
A. AA ROUTINE H&E X1 BLOCK.16
H&E X1

Prep

Source: NCI Genomic Data Commons file d7df163a-7378-441b-9706-89a6ce3fe98e (TCGA-IZ-8195.77742F61-026C-4095-A666-2B3FEC8094E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).